Somatic mutation profile of tumor specimen TCGA-96-7544-01A (aliquot TCGA-96-7544-01A-11D-2042-08) from TCGA case TCGA-96-7544, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.6 years (30,548 days).
Specimen TCGA-96-7544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66f0f79-fd6e-4a07-900c-689cd0af62ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-7544-10A (Blood Derived Normal), aliquot TCGA-96-7544-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9466d69-817d-482a-a6bc-1d8f80d6b745

The open-access MAF lists 433 somatic variants for this specimen: 335 protein-altering or splice-affecting, 87 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 87, Nonsense Mutation 28, Splice Site 9, Frame Shift Del 7, RNA 5, Splice Region 3, 5'Flank 3, Intron 2, 5'UTR 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBB | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs33918338, CM056597, CM066867, COSV100092531; ClinVar: pathogenic / other; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2161G>T p.V721L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99771161; called by muse, mutect2, varscan2
- ABCA13 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs376264174; called by muse, mutect2, varscan2
- ABCG8 | c.1488+2T>A p.X496_splice | Splice Site (SNP) | VAF 38/132 reads (29%) | catalogued as COSV99699365; called by muse, mutect2, varscan2
- AC013489.1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757902237, COSV51553976; called by muse, mutect2, varscan2
- ACADL | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV99284474; called by muse, mutect2, varscan2
- ACTL7A | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV100452992; called by muse, mutect2, varscan2
- ACTL9 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100185065; called by muse, mutect2, varscan2
- ADAM29 | c.239T>A p.V80E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821868; called by muse, mutect2, varscan2
- ADARB2 | c.2042G>C p.R681T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV101184516; called by muse, mutect2, varscan2
- ADGRE1 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV99164990; called by muse, mutect2, varscan2
- AHNAK | c.8173G>T p.V2725L | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as COSV99945239; called by muse, mutect2, varscan2
- AIM2 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100930997; called by muse, mutect2, varscan2
- ALDH1L1 | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV99856368; called by muse, mutect2, varscan2
- ALPK1 | c.1289G>T p.R430I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99452864; called by muse, mutect2, varscan2
- ANK1 | c.3328-1G>T p.X1110_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99223590; called by muse, mutect2, varscan2
- ANKRD17 | c.3881C>G p.S1294C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100428405; called by muse, mutect2
- ANKS1B | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as COSV100242210; called by muse, mutect2, varscan2
- ANO5 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100201297; called by muse, mutect2, varscan2
- ARFGEF1 | c.4529T>C p.L1510P | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.786); catalogued as COSV99141005; called by muse, mutect2, varscan2
- ARMC9 | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV100589447; called by muse, mutect2, varscan2
- ARPP21 | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99490556; called by muse, mutect2, varscan2
- ART4 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966777; called by muse, mutect2, varscan2
- ASAP1 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63050794; called by muse, mutect2, varscan2
- ASXL3 | c.5817G>C p.R1939S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99322924; called by muse, mutect2, varscan2
- ATG9B | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100939857; called by muse, mutect2, varscan2
- ATRNL1 | c.2713G>T p.E905* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100369005, COSV100372927; called by muse, mutect2, varscan2
- BANK1 | c.2112G>T p.W704C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100535667; called by muse, mutect2, varscan2
- BCAS1 | c.243del p.E83Rfs*15 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV101005977; called by mutect2, pindel, varscan2
- BPTF | c.2975A>G p.K992R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.057); catalogued as rs1391005221, COSV58835743; called by muse, mutect2
- BRCA2 | c.5147A>G p.Y1716C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101203836; called by muse, mutect2, varscan2
- BRWD1 | c.4957G>T p.E1653* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100312633; called by muse, mutect2, varscan2
- C1QC | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009384; called by muse, mutect2, varscan2
- C2CD3 | c.5658C>G p.L1886= | Splice Region (SNP) | VAF 9/66 reads (14%) | catalogued as COSV58092997; called by muse, mutect2, varscan2
- C2orf78 | c.685T>A p.Y229N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV101280891; called by muse, mutect2, varscan2
- CCAR1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); catalogued as rs1329500093, COSV99770492; called by muse, mutect2, varscan2
- CCDC141 | c.4173G>C p.E1391D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV55376721, COSV99836035; called by muse, mutect2, varscan2
- CCDC170 | c.1948C>A p.L650M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99498043; called by muse, mutect2, varscan2
- CCDC33 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV58353928; called by muse, mutect2, varscan2
- CCDC54 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99660110; called by muse, mutect2, varscan2
- CCER1 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100726922; called by muse, mutect2, varscan2
- CCNL1 | c.1168A>G p.R390G | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV99904357; called by muse, mutect2, varscan2
- CD5L | c.888A>T p.R296S | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100940972; called by muse, mutect2, varscan2
- CDH10 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100049742; called by muse, mutect2, varscan2
- CDH10 | c.1361G>C p.W454S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100049745, COSV52582068; called by muse, mutect2, varscan2
- CDK12 | c.4086G>C p.L1362F (on ENST00000447079 / NM_016507.4; = p.L1353F on NM_015083.3) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV71001395; called by muse, mutect2, varscan2
- CEACAM20 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as COSV100386749; called by muse, mutect2, varscan2
- CENPF | c.408T>A p.D136E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs1197502174, COSV100871435; called by muse, mutect2, varscan2
- CENPF | c.4958G>T p.R1653L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs1223818651, COSV100871436; called by muse, mutect2, varscan2
- CEP72 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99374388; called by muse, mutect2, varscan2
- CFH | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100808583; called by muse, mutect2, varscan2
- CHRD | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99200222; called by muse, mutect2, varscan2
- CHRNB3 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99250801; called by muse, mutect2, varscan2
- CHRND | c.510T>C p.S170= | Splice Region (SNP) | VAF 29/73 reads (40%) | catalogued as COSV99285464; called by muse, mutect2, varscan2
- CLDN11 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99290871; called by muse, mutect2, varscan2
- CLSTN2 | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV101515423; called by muse, mutect2, varscan2
- COL27A1 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs781235729, COSV100620675; called by muse, mutect2, varscan2
- COL3A1 | c.1816-1G>T p.X606_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100482273, COSV58588114; called by muse, mutect2, varscan2
- COL3A1 | c.1816G>T p.G606C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1412536, COSV100482276, COSV58583021; called by muse, mutect2, varscan2
- COL6A6 | c.4336G>T p.G1446C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649670; called by muse, mutect2, varscan2
- CPA4 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99744526; called by muse, mutect2, varscan2
- CRP | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 63/239 reads (26%) | catalogued as COSV99660370, COSV99660464; called by muse, mutect2, varscan2
- CSF1R | c.2674T>C p.C892R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640655; called by muse, mutect2, varscan2
- CTDP1 | c.792del p.K265Sfs*50 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | catalogued as COSV99310729; called by mutect2, pindel, varscan2
- DAPK1 | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800767; called by muse, mutect2, varscan2
- DCC | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100497562; called by muse, mutect2, varscan2
- DEFB119 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53619910, COSV99489091; called by muse, mutect2, varscan2
- DIP2A | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59476951; called by muse, mutect2, varscan2
- DMBT1 | c.5554G>A p.G1852S (on ENST00000338354 / NM_001377530.1; = p.G1095S on NM_004406.3) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100351843, COSV100352928; called by muse, mutect2, varscan2
- DMD | c.6275A>G p.Y2092C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs745717858, COSV100817314; called by muse, mutect2, varscan2
- DNAH11 | c.4115A>T p.K1372M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100176362; called by muse, mutect2, varscan2
- DNAH5 | c.11281G>C p.E3761Q | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99443802; called by muse, mutect2, varscan2
- DNAH5 | c.6757A>T p.R2253* | Nonsense Mutation (SNP) | VAF 48/79 reads (61%) | catalogued as COSV99443803; called by muse, mutect2, varscan2
- DNAH8 | c.9136A>G p.I3046V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs1297335634, COSV100542842; called by muse, mutect2, varscan2
- DOCK3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs756421617, COSV56539986; called by muse, mutect2, varscan2
- DPPA3 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100559796; called by muse, mutect2, varscan2
- DSCAM | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV101258823; called by muse, mutect2, varscan2
- DSEL | c.2108G>T p.R703I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs774188376, COSV100025041; called by muse, mutect2, varscan2
- DTX3L | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949814; called by muse, mutect2, varscan2
- DTX3L | c.2194G>C p.E732Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs767940689, COSV99949778, COSV99949816; called by muse, mutect2, varscan2
- DYNC1H1 | c.3913G>C p.E1305Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100794237, COSV100795266; called by muse, mutect2, varscan2
- EIF2A | c.1628A>T p.K543I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99855694; called by muse, mutect2, varscan2
- EIF2AK4 | c.3929A>G p.Q1310R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV99773885; called by muse, mutect2, varscan2
- EMILIN1 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV100980096; called by muse, mutect2, varscan2
- ENAM | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as COSV101252873; called by muse, mutect2, varscan2
- ENPP1 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV62930385; called by muse, mutect2, varscan2
- EPAS1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99762770, COSV99762798; called by muse, mutect2, varscan2
- EPB41L2 | c.1858G>C p.D620H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100440089; called by muse, mutect2, varscan2
- ERCC2 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV55541956, COSV99675998; called by muse, mutect2, varscan2
- EVPL | c.4036G>A p.A1346T | Missense Mutation (SNP) | VAF 164/254 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100043763; called by muse, mutect2, varscan2
- FAM160B2 | c.2170G>C p.V724L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99248660; called by muse, mutect2, varscan2
- FAM161B | c.1011G>C p.Q337H (on ENST00000651776; = p.Q274H on NM_152445.3) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV54103940; called by muse, mutect2, varscan2
- FAM186B | c.2221T>C p.Y741H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99217635; called by muse, mutect2, varscan2
- FAM90A1 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100274138; called by muse, mutect2, varscan2
- FAR2 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99478603; called by muse, mutect2, varscan2
- FAT3 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 39/253 reads (15%) | catalogued as COSV99960503; called by muse, mutect2, varscan2
- FBXO3 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1253898952, COSV99682036; called by muse, mutect2, varscan2
- FCRL4 | c.1250-2A>T p.X417_splice | Splice Site (SNP) | VAF 28/104 reads (27%) | catalogued as COSV99619157; called by muse, mutect2, varscan2
- FDXR | c.1324C>T p.Q442* (on ENST00000293195 / NM_024417.5; = p.Q448* on NM_004110.6) | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as rs1004910556, COSV99500489; called by muse, mutect2, varscan2
- FEZF2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV99334464; called by muse, mutect2, varscan2
- FGD5 | c.2389G>C p.A797P | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV99547106; called by muse, mutect2, varscan2
- FLVCR2 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99470974; called by muse, mutect2, varscan2
- FMN2 | c.4688A>T p.Q1563L | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100142112; called by muse, varscan2
- FRAS1 | c.3593A>G p.D1198G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99347498; called by muse, mutect2, varscan2
- FSHR | c.561C>A p.N187K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.669); catalogued as rs777027304, COSV100436376; called by muse, mutect2, varscan2
- GAPVD1 | c.54A>T p.L18F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99782511; called by muse, mutect2, varscan2
- GCN1 | c.4060C>T p.Q1354* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100324522; called by muse, mutect2, varscan2
- GFI1 | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99647350; called by muse, mutect2, varscan2
- GLB1L3 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs771628588, COSV101345118; called by mutect2, varscan2
- GLP1R | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100952431; called by muse, mutect2, varscan2
- GP2 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1174542918, COSV100221193; called by muse, mutect2, varscan2
- GRIN3A | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV100701484, COSV62457873; called by muse, mutect2, varscan2
- GTF3C2 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99272047; called by muse, mutect2, varscan2
- H3C8 | c.81del p.S29Afs*8 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as COSV59953748; called by mutect2, pindel, varscan2
- HELZ2 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100915402; called by muse, mutect2, varscan2
- HMGCLL1 | c.630A>G p.R210= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99231213; called by muse, mutect2, varscan2
- HMGXB4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99329862; called by muse, mutect2, varscan2
- HOXD10 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV50895598; called by muse, mutect2, varscan2
- HUWE1 | c.7069G>C p.E2357Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99470273; called by muse, mutect2, varscan2
- HYDIN | c.13867G>A p.G4623R | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1023885464, COSV101124806; called by muse, mutect2, varscan2
- IFRD1 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV99133533; called by muse, mutect2, varscan2
- IFT74 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV101195760; called by muse, mutect2, varscan2
- IGSF21 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99243420; called by muse, mutect2, varscan2
- INTS6 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100246853, COSV60879925; called by muse, mutect2, varscan2
- ITGA8 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100958676; called by muse, mutect2, varscan2
- ITGB8 | c.1385A>G p.H462R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as COSV99750372; called by muse, mutect2, varscan2
- KCNT2 | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1246298728, COSV99650950; called by muse, mutect2, varscan2
- KCTD3 | c.959G>T p.S320I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99378730; called by muse, mutect2, varscan2
- KIAA0319L | c.3129C>G p.S1043R | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV100356692; called by muse, mutect2, varscan2
- KIRREL2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52879425; called by muse, mutect2, varscan2
- KL | c.2629G>A p.D877N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101198960; called by muse, mutect2, varscan2
- KLC3 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101228775; called by muse, mutect2, varscan2
- KLF14 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.164); catalogued as COSV100205802; called by muse, mutect2, varscan2
- KLF15 | c.314G>T p.W105L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV99955035; called by muse, mutect2
- KLHL24 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.785); catalogued as COSV99664648; called by muse, mutect2, varscan2
- KMT2D | c.6247C>T p.Q2083* | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as COSV99976768; called by muse, mutect2, varscan2
- KRT5 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52862749, COSV99357714; called by muse, mutect2, varscan2
- KRT73 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1399580761, COSV59840400, COSV99988195; called by muse, varscan2
- LAMA1 | c.4966G>T p.D1656Y | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs532060695, COSV101054641; called by muse, mutect2, varscan2
- LAP3 | c.1530C>G p.F510L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99883971; called by muse, mutect2, varscan2
- LATS1 | c.3331T>G p.S1111A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as COSV99485056; called by muse, mutect2, varscan2
- LGR4 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003808; called by muse, mutect2, varscan2
- LGSN | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV101040171; called by muse, mutect2, varscan2
- LGSN | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101040172; called by muse, mutect2
- LILRB1 | c.2105A>G p.*702Wext*52 (on ENST00000427581; = p.*651Wext*52 on NM_006669.6) | Nonstop Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100206786; called by muse, mutect2, varscan2
- LINGO1 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs539526244, COSV62438616; called by muse, mutect2, varscan2
- LMO3 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV99662538; called by muse, mutect2, varscan2
- LRP1 | c.10511C>T p.S3504L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs142721778; called by muse, mutect2, varscan2
- LRP1B | c.4335G>T p.R1445S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101250649; called by muse, mutect2, varscan2
- LRRK2 | c.3075C>A p.S1025R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs199585333, COSV100108808; called by muse, mutect2, varscan2
- LVRN | c.2653A>T p.T885S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100773277; called by muse, mutect2
- LY75 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99715785; called by muse, mutect2, varscan2
- MAGEC2 | c.274C>G p.P92A | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as COSV99909344; called by muse, mutect2, varscan2
- MAGED1 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV100431337; called by muse, mutect2, varscan2
- MAP2 | c.4652G>A p.R1551Q | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775158582, COSV99557375; called by muse, mutect2, varscan2
- MAP2K7 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425924011, COSV67610068; called by muse, mutect2, varscan2
- MAP3K11 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs751118360, COSV100442004; called by muse, mutect2, varscan2
- MAPRE1 | c.121+1G>A p.X41_splice | Splice Site (SNP) | VAF 25/102 reads (25%) | catalogued as rs1442564081, COSV100980378; called by muse, mutect2, varscan2
- MASP1 | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396667; called by muse, mutect2, varscan2
- MBD1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs1321409301, COSV99495256; called by muse, mutect2, varscan2
- MBNL1 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.274); catalogued as COSV99219270; called by muse, mutect2, varscan2
- MCM4 | c.1800+1G>A p.X600_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100031155; called by muse, mutect2, varscan2
- MMACHC | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758426429, COSV99423364; called by muse, mutect2, varscan2
- MMP17 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.339); catalogued as COSV100861841; called by muse, mutect2
- MOGS | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV99270219; called by muse, mutect2, varscan2
- MPHOSPH6 | c.412T>G p.Y138D | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99259050; called by muse, mutect2, varscan2
- MROH2B | c.4445G>T p.R1482M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV101270436; called by muse, mutect2, varscan2
- MS4A13 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100981001; called by muse, mutect2
- MUC16 | c.35774C>T p.S11925F | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV101197490; called by muse, mutect2, varscan2
- MUC16 | c.26396A>G p.Q8799R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as rs752110196, COSV101197491; called by muse, mutect2, varscan2
- MUC3A | c.7693T>C p.S2565P | Missense Mutation (SNP) | VAF 103/512 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100113819; called by muse, mutect2, varscan2
- MUC5AC | c.16049G>T p.R5350L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.081); catalogued as COSV100611276; called by muse, varscan2
- MUC5B | c.2411G>T p.S804I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV101499966; called by muse, varscan2
- MVB12A | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); catalogued as COSV100396380, COSV100396605; called by muse, mutect2
- MXRA8 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100491766, COSV100491958; called by muse, mutect2, varscan2
- MYH7B | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV99482173; called by muse, mutect2, varscan2
- MYO16 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51813694, COSV99193422; called by muse, mutect2, varscan2
- MYO3A | c.3870C>G p.S1290R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); catalogued as COSV56321869, COSV99777807; called by muse, mutect2
- MYOF | c.4372T>C p.Y1458H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100825085; called by muse, mutect2, varscan2
- NADSYN1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 37/172 reads (22%) | catalogued as COSV100034366, COSV59811962; called by muse, mutect2, varscan2
- NBEAL1 | c.7774G>T p.D2592Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV101355352; called by muse, mutect2, varscan2
- NDST4 | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99995194; called by muse, mutect2, varscan2
- NGB | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as COSV100030003; called by muse, mutect2, varscan2
- NLRP1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV99332767; called by muse, mutect2, varscan2
- NLRP11 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100789609; called by muse, mutect2, varscan2
- NLRP5 | c.2218G>T p.V740F | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV101173303; called by muse, mutect2, varscan2
- NOLC1 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100893537; called by muse, mutect2, varscan2
- NPAP1 | c.3118C>A p.Q1040K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.118); catalogued as COSV100274634; called by muse, mutect2, varscan2
- NPHS1 | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100799548; called by muse, mutect2, varscan2
- NRG3 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64553834; called by muse, mutect2, varscan2
- NUP210L | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99667023; called by muse, mutect2, varscan2
- NXPE1 | c.440C>G p.A147G (on ENST00000424269; = p.A5G on NM_152315.5) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV52627833, COSV99319810; called by muse, mutect2, varscan2
- OR14J1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV65845825; called by muse, mutect2, varscan2
- OR1S2 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100223992; called by muse, mutect2, varscan2
- OR2B3 | c.783A>C p.Q261H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101013737; called by mutect2, varscan2
- OR2F2 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV101283790, COSV68833464; called by muse, mutect2, varscan2
- OR2G6 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs964299406, COSV100597995; called by muse, mutect2, varscan2
- OR2T2 | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100737528; called by muse, mutect2, varscan2
- OR2T27 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100788078; called by muse, varscan2
- OR2T34 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60900558; called by muse, mutect2
- OR4C6 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV58605185; called by muse, mutect2, varscan2
- OR6C65 | c.849G>C p.L283F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV101110164, COSV101110216; called by muse, mutect2, varscan2
- OTX2 | c.404C>A p.S135Y (on ENST00000408990 / NM_172337.3; = p.S143Y on NM_021728.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as COSV100257725; called by muse, mutect2, varscan2
- PAPPA2 | c.3331G>T p.G1111* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100867435, COSV62813650; called by muse, mutect2, varscan2
- PARD3B | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as COSV100591837; called by muse, mutect2, varscan2
- PAXBP1 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51613281, COSV99268946; called by muse, mutect2, varscan2
- PCDHB4 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV52027775; called by muse, mutect2, varscan2
- PCDHGA8 | c.2025G>T p.L675F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99528843; called by muse, mutect2, varscan2
- PDE8B | c.2611C>A p.L871I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV99365973; called by muse, mutect2, varscan2
- PEX5 | c.1631C>T p.A544V (on ENST00000420616; = p.A536V on NM_000319.5) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs367586808; called by muse, mutect2, varscan2
- PEX5L | c.1350T>G p.D450E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99827721; called by muse, mutect2, varscan2
- PGAM2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs1426478791, COSV99803451; called by muse, mutect2, varscan2
- PGLYRP3 | c.376+1G>T p.X126_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99319423; called by muse, mutect2, varscan2
- PGM1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV100936455; called by muse, mutect2, varscan2
- PHF3 | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100012789, COSV50325972; called by muse, mutect2, varscan2
- PIK3AP1 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100225415, COSV100225817; called by muse, mutect2, varscan2
- PIK3CG | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100782437, COSV63246812; called by muse, mutect2, varscan2
- PIN1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321408; called by muse, mutect2, varscan2
- PLCXD3 | c.310A>T p.R104* | Nonsense Mutation (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100125064; called by muse, mutect2, varscan2
- PLP1 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.468); catalogued as CM114561, COSV100393225; called by muse, mutect2, varscan2
- PPP1R36 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100072648; called by muse, mutect2, varscan2
- PRDM9 | c.2424G>T p.E808D | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as COSV57003678; called by muse, varscan2
- PRICKLE2 | c.1120G>A p.G374S (on ENST00000295902; = p.G318S on NM_198859.4) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV99896493; called by muse, mutect2, varscan2
- PSG3 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs759718102, COSV100548623; called by muse, mutect2, varscan2
- PTCD1 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99463062; called by muse, mutect2, varscan2
- PTGER2 | c.840C>G p.F280L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99817266; called by muse, mutect2, varscan2
- PTP4A3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 105/192 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61472549; called by muse, mutect2, varscan2
- PXDN | c.4047G>C p.K1349N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99411974, COSV99413354; called by muse, varscan2
- RAD51B | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV101184782; called by muse, mutect2, varscan2
- RAD9B | c.794T>C p.M265T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); catalogued as rs771219120, COSV100799243; called by muse, mutect2, varscan2
- RAI14 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99461543; called by muse, mutect2, varscan2
- RB1CC1 | c.4152G>C p.K1384N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV99205194; called by muse, mutect2
- RCVRN | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99874048; called by muse, mutect2, varscan2
- RGS7 | c.860C>G p.T287R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.924); catalogued as COSV58550062, COSV58557354; called by muse, mutect2, varscan2
- RNASE3 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV58960276; called by muse, mutect2, varscan2
- RP1 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99605885; called by muse, mutect2, varscan2
- RYR2 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100767277; called by muse, mutect2, varscan2
- SAC3D1 | c.991A>T p.S331C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV100100733; called by muse, mutect2, varscan2
- SAGE1 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100186514, COSV61014352; called by muse, mutect2, varscan2
- SATL1 | c.754C>G p.R252G (on ENST00000395409; = p.R439G on NM_001012980.2) | Missense Mutation (SNP) | VAF 76/108 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100260630, COSV60576193; called by muse, mutect2, varscan2
- SCN2A | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99329775; called by muse, mutect2, varscan2
- SCNN1A | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV99964419; called by muse, mutect2, varscan2
- SDK2 | c.4562G>A p.R1521Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs766490350, COSV101166594; called by muse, varscan2
- SELE | c.885G>C p.E295D | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as COSV100324421, COSV60978304; called by muse, mutect2, varscan2
- SI | c.2846T>C p.L949S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.102); catalogued as COSV100013543; called by muse, mutect2, varscan2
- SI | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs1247427505, COSV52285353, COSV52298193; called by muse, mutect2
- SIGLEC7 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs964921109, COSV58316845, COSV99978366; called by muse, mutect2, varscan2
- SIPA1L2 | c.1197T>A p.D399E | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV99476944; called by muse, mutect2, varscan2
- SLC17A8 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035084; called by muse, mutect2, varscan2
- SLC17A8 | c.676+1G>T p.X226_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100035087; called by muse, mutect2, varscan2
- SLC25A13 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs1472269685, COSV99672924; called by muse, mutect2, varscan2
- SLC25A35 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV99873637; called by muse, mutect2, varscan2
- SLC25A53 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV100655806; called by muse, mutect2, varscan2
- SLC35C2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1329275416, COSV54758251; called by muse, mutect2, varscan2
- SLC35F4 | c.1489G>C p.D497H (on ENST00000339762 / NM_001352015.2; = p.D461H on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV100333446; called by muse, mutect2, varscan2
- SLC39A12 | c.1706C>A p.S569* (on ENST00000377369 / NM_001145195.2; = p.S532* on NM_152725.3) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV101069791; called by muse, mutect2, varscan2
- SLC39A14 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99249498; called by muse, mutect2, varscan2
- SLC8A1 | c.1273G>T p.V425L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.641); catalogued as COSV100244064; called by muse, mutect2, varscan2
- SLCO1A2 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100261218; called by muse, mutect2, varscan2
- SLCO2A1 | c.1215C>G p.I405M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.077); catalogued as COSV100188597; called by muse, mutect2, varscan2
- SLIT1 | c.3425G>C p.C1142S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99820425; called by muse, mutect2, varscan2
- SOGA3 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs867516142, COSV100846730, COSV100847091; called by muse, mutect2, varscan2
- SST | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV99809748, COSV99809816; called by muse, mutect2, varscan2
- SSU72 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99357125; called by muse, mutect2
- STAB2 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185565; called by muse, mutect2, varscan2
- SUOX | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs901265557, COSV99906900; called by muse, mutect2, varscan2
- SYCP1 | c.2450C>A p.S817* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV101050710; called by muse, mutect2, varscan2
- SYNE1 | c.22979G>T p.R7660L (on ENST00000367255 / NM_182961.4; = p.R7589L on NM_033071.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV55074278, COSV99550606; called by muse, mutect2, varscan2
- SYNE1 | c.11212G>C p.V3738L (on ENST00000367255 / NM_182961.4; = p.V3723L on NM_033071.3) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99550609; called by muse, mutect2, varscan2
- TAAR8 | c.785C>G p.T262R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV51585961, COSV51586026, COSV99257005; called by muse, mutect2, varscan2
- TAF3 | c.2000G>T p.S667I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV100719772; called by muse, mutect2, varscan2
- TBX4 | c.1631A>C p.D544A | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV99539799; called by muse, mutect2, varscan2
- TBXAS1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs769738510, COSV54944808; called by muse, mutect2, varscan2
- TCEAL6 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV101035892; called by muse, mutect2, varscan2
- TDRD9 | c.1691G>T p.R564L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV59144240, COSV59152680; called by muse, mutect2, varscan2
- TENM1 | c.5140A>T p.T1714S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV100948824; called by muse, mutect2, varscan2
- TEP1 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52989817, COSV99401446; called by muse, mutect2, varscan2
- THSD7B | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55648336, COSV55742726; called by muse, mutect2, varscan2
- THSD7B | c.3538G>T p.E1180* (on ENST00000272643; = p.E1178* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 52/161 reads (32%) | catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TIAM1 | c.3077G>T p.G1026V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as COSV99732119; called by muse, mutect2, varscan2
- TIMM17A | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs527454908, COSV100938955; called by muse, mutect2, varscan2
- TKTL2 | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99761001; called by muse, mutect2, varscan2
- TLK2 | c.1474A>G p.I492V (on ENST00000326270 / NM_001284333.2; = p.I470V on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.251); catalogued as COSV58298812; called by muse, mutect2, varscan2
- TMEM132D | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV70602594; called by muse, mutect2, varscan2
- TMEM178A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as COSV99931705, COSV99931835; called by muse, mutect2, varscan2
- TMEM9 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV100947334; called by muse, mutect2, varscan2
- TNFRSF4 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs774474644, COSV99767286; called by muse, varscan2
- TNKS2 | c.3028A>T p.T1010S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100860962; called by muse, mutect2, varscan2
- TNN | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99510888; called by muse, mutect2, varscan2
- TNR | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99686987, COSV99687755; called by muse, mutect2, varscan2
- TNXB | c.6643G>A p.V2215I (on ENST00000647633; = p.V1968I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV100925682; called by muse, mutect2, varscan2
- TOR1AIP1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs756916997, COSV54869213; called by muse, mutect2, varscan2
- TPX2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs776728395, COSV55921184; called by muse, mutect2, varscan2
- TRBC2 | c.217A>T p.R73* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs1335434228; called by muse, mutect2, varscan2
- TRBV28 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as rs1048776616; called by muse, mutect2, varscan2
- TRHDE | c.1182T>G p.D394E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99668656; called by muse, mutect2, varscan2
- TRIM16L | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1182733090, COSV101192577; called by muse, mutect2, varscan2
- TRIM49 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV100315845; called by muse, mutect2, varscan2
- TRIP6 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV99566408; called by muse, mutect2, varscan2
- TRPC3 | c.1670T>A p.F557Y (on ENST00000379645 / NM_001366479.2; = p.F484Y on NM_003305.2) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99311977; called by muse, mutect2, varscan2
- TRPC7 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1270710457, COSV100725376, COSV61453499, COSV61465577; called by muse, mutect2, varscan2
- TRPS1 | c.2272G>T p.E758* (on ENST00000220888 / NM_001330599.2; = p.E771* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 180/316 reads (57%) | catalogued as COSV55224485, COSV55267873; called by muse, mutect2, varscan2
- TSPOAP1 | c.4793G>C p.R1598T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV52115801, COSV99271656; called by muse, mutect2, varscan2
- TTC13 | c.1125+2T>G p.X375_splice | Splice Site (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100792830; called by muse, mutect2, varscan2
- TTN | c.93146C>G p.P31049R (on ENST00000591111; = p.P23625R on NM_003319.4) | Missense Mutation (SNP) | VAF 41/148 reads (28%) | PolyPhen probably damaging (0.999); catalogued as COSV100590566; called by muse, mutect2, varscan2
- TTN | c.20191C>T p.R6731* (on ENST00000591111; = p.R5804* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs770579313, COSV100590570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.10738G>T p.D3580Y (on ENST00000591111; = p.D3534Y on NM_003319.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as rs1300532206, COSV100590574; called by muse, mutect2, varscan2
- UAP1L1 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814391; called by muse, mutect2, varscan2
- UGDH | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100328284; called by muse, mutect2, varscan2
- URB2 | c.1246A>T p.I416L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99270526; called by muse, mutect2, varscan2
- URGCP | c.1466A>G p.Y489C (on ENST00000453200 / NM_001077663.3; = p.Y480C on NM_017920.4) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV99786874; called by muse, mutect2, varscan2
- USH2A | c.14009A>T p.Y4670F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as COSV100227908; called by muse, mutect2, varscan2
- USH2A | c.6599T>C p.F2200S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100227910; called by muse, mutect2, varscan2
- VCAM1 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99658130; called by muse, mutect2, varscan2
- VPS13D | c.7338G>T p.K2446N | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99165331; called by muse, mutect2, varscan2
- WDR17 | c.166T>C p.C56R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706551; called by muse, mutect2, varscan2
- WDR24 | c.1427G>C p.G476A (on ENST00000248142; = p.G346A on NM_032259.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV99555312; called by mutect2, varscan2
- WDR82 | c.419A>C p.N140T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV99626511; called by muse, mutect2, varscan2
- WFDC5 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV100331941; called by muse, mutect2, varscan2
- YEATS2 | c.1736T>G p.I579R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV100527380; called by muse, mutect2, varscan2
- ZAN | c.7500G>C p.K2500N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100768995; called by muse, mutect2, varscan2
- ZMYM1 | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100720870; called by muse, mutect2, varscan2
- ZNF229 | c.1710A>T p.K570N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99349932; called by muse, mutect2, varscan2
- ZNF419 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs772971471, COSV99691734; called by muse, mutect2, varscan2
- ZNF419 | c.1230G>C p.E410D | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99691738; called by muse, mutect2, varscan2
- ZNF438 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV100061084; called by muse, mutect2, varscan2
- ZNF460 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100828008; called by muse, mutect2, varscan2
- ADGRE1 | c.270del p.C91Vfs*19 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel*
- CDH12 | c.148del p.Q50Nfs*33 | Frame Shift Del (DEL) | VAF 139/316 reads (44%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.4088_4100del p.Q1363Pfs*47 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- IGHV5-51 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL17REL | c.731_739del p.G244_K247delinsE | In Frame Del (DEL) | VAF 37/79 reads (47%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 106/510 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- SETX | c.6166del p.V2056Ffs*2 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- ABCF3 | c.858A>C p.A286= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99490229; called by muse, mutect2, varscan2
- ADAMTS19 | c.1137T>A p.R379= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99176196; called by muse, mutect2, varscan2
- ADGRA1 | c.138C>A p.I46= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV101192616; called by muse, mutect2, varscan2
- ADGRV1 | c.4107A>T p.G1369= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1165727183, COSV101315349; called by muse, mutect2, varscan2
- ADPRH | c.330G>A p.L110= | Silent (SNP) | VAF 64/212 reads (30%) | catalogued as COSV100813253; called by muse, mutect2, varscan2
- AGTPBP1 | c.3348A>G p.L1116= (on ENST00000357081 / NM_001330701.2; = p.L1076= on NM_015239.2) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100429153; called by muse, mutect2, varscan2
- AHNAK | c.12189G>T p.V4063= | Silent (SNP) | VAF 56/288 reads (19%) | catalogued as COSV99945236; called by muse, mutect2, varscan2
- ASH1L | c.4464A>G p.K1488= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV100853054; called by muse, mutect2, varscan2
- ASTN1 | c.1080C>G p.T360= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99920146, COSV99923292; called by muse, mutect2, varscan2
- ATMIN | c.756C>A p.I252= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100214477; called by muse, mutect2, varscan2
- BICD1 | c.2796A>T p.P932= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99861897; called by muse, mutect2, varscan2
- BIRC3 | c.750G>C p.L250= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs924808678, COSV99679629; called by muse, mutect2, varscan2
- BPIFB6 | c.7C>A p.R3= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs370471311, COSV100848466; called by muse, mutect2, varscan2
- BRS3 | c.972C>T p.C324= | Silent (SNP) | VAF 57/106 reads (54%) | catalogued as rs756871495, COSV65711280; called by muse, mutect2, varscan2
- C11orf49 | c.579G>C p.T193= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV53564415, COSV99561485; called by muse, mutect2, varscan2
- C1QTNF6 | c.138C>T p.L46= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99742135; called by muse, mutect2, varscan2
- CDH9 | c.1527C>T p.V509= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as COSV99141236; called by muse, mutect2, varscan2
- CLCA4 | c.2622C>T p.D874= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100990925; called by muse, mutect2, varscan2
- COL12A1 | c.378A>G p.G126= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100485217; called by muse, mutect2, varscan2
- CPN1 | c.138G>T p.T46= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100962525; called by muse, mutect2, varscan2
- CPS1 | c.567T>A p.P189= | Silent (SNP) | VAF 89/143 reads (62%) | catalogued as COSV99241719; called by muse, mutect2, varscan2
- DDX11 | c.1464C>T p.D488= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99298809; called by muse, mutect2, varscan2
- DENND4A | c.2901C>G p.L967= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101475245; called by muse, mutect2, varscan2
- DGCR6L | c.219C>T p.L73= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV50619906; called by muse, mutect2, varscan2
- DMAC1 | c.192C>T p.Y64= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100830274; called by muse, mutect2, varscan2
- EVC2 | c.603G>T p.S201= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100184804, COSV60403141; called by muse, mutect2, varscan2
- EYS | c.579T>C p.A193= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100675520; called by muse, mutect2, varscan2
- FER1L5 | c.5487G>T p.T1829= (on ENST00000623019; = p.T1793= on NM_001293083.2) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs770079760, COSV99383006; called by muse, mutect2, varscan2
- FIBCD1 | c.1068C>T p.S356= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs935671677, COSV99446564; called by muse, mutect2, varscan2
- FSCB | c.2208T>C p.A736= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100468736; called by muse, mutect2, varscan2
- GAGE2E | c.213G>A p.K71= | Silent (SNP) | VAF 59/649 reads (9%) | called by muse, varscan2
- GRIN2A | c.570A>T p.T190= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100407731; called by muse, mutect2, varscan2
- GTDC1 | c.525C>T p.F175= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99599171; called by muse, mutect2, varscan2
- GXYLT2 | c.948A>G p.L316= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs769059944, COSV101274601; called by muse, mutect2, varscan2
- IBA57 | c.600C>G p.T200= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100812745; called by muse, mutect2, varscan2
- IDO2 | c.1122T>A p.P374= (on ENST00000389060; = p.P387= on NM_194294.2) | Silent (SNP) | VAF 74/156 reads (47%) | catalogued as COSV100584461; called by muse, mutect2, varscan2
- IGHG2 | c.630C>A p.P210= | Silent (SNP) | VAF 70/312 reads (22%) | called by muse, mutect2, varscan2
- IQGAP3 | c.2580C>A p.L860= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100752339; called by muse, mutect2
- JAKMIP2 | c.1503C>A p.G501= | Silent (SNP) | VAF 100/261 reads (38%) | catalogued as COSV99507151; called by muse, mutect2, varscan2
- KIF18A | c.1167A>G p.E389= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99588164; called by muse, mutect2
- KIR2DL4 | c.540C>T p.N180= (on ENST00000396284; = p.N141= on NM_001080770.2) | Silent (SNP) | VAF 58/322 reads (18%) | catalogued as rs777887229; called by muse, varscan2
- KLHDC4 | c.903G>T p.V301= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99565912; called by muse, mutect2, varscan2
- MAST2 | c.2190G>A p.P730= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs748978935, COSV63616373; called by muse, mutect2, varscan2
- MPEG1 | c.1587C>A p.G529= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs201332555, COSV57089348, COSV99914890; called by muse, mutect2, varscan2
- MYO18B | c.2946G>C p.R982= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100122351, COSV100124314; called by muse, mutect2, varscan2
- NAALADL2 | c.672A>T p.P224= | Silent (SNP) | VAF 61/137 reads (45%) | catalogued as COSV101458161, COSV70295498; called by muse, mutect2, varscan2
- NCF2 | c.945C>T p.S315= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs200655126, COSV62314884; called by muse, mutect2, varscan2
- NFKB1 | c.2841A>T p.S947= (on ENST00000394820 / NM_001382627.1; = p.S948= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs771506547, COSV99896526; called by muse, mutect2, varscan2
- NUP160 | c.2268T>C p.F756= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101021216; called by muse, mutect2, varscan2
- OR2B11 | c.564G>C p.V188= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs746052771, COSV100275094, COSV100276829; called by muse, mutect2, varscan2
- OR2M3 | c.552A>C p.L184= | Silent (SNP) | VAF 54/221 reads (24%) | catalogued as COSV101513389, COSV71758990; called by muse, mutect2, varscan2
- OR4F15 | c.324G>T p.G108= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV100173804; called by muse, mutect2, varscan2
- OR4K5 | c.402C>T p.V134= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as COSV100262076; called by muse, mutect2, varscan2
- OR5B3 | c.861C>G p.V287= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs572981565, COSV100511778, COSV100511997; called by muse, mutect2, varscan2
- OR5D14 | c.417A>T p.S139= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100162033; called by muse, mutect2, varscan2
- PADI1 | c.822G>T p.P274= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as COSV64937758; called by muse, mutect2, varscan2
- PCDHGA10 | c.1776G>T p.V592= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV99528845; called by muse, mutect2, varscan2
- PI4KB | c.1146C>G p.P382= (on ENST00000368873 / NM_001369623.1; = p.P394= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs769708110, COSV55020814, COSV99649217; called by muse, mutect2
- PIKFYVE | c.4983A>T p.A1661= | Silent (SNP) | VAF 90/132 reads (68%) | catalogued as COSV100009532; called by muse, mutect2, varscan2
- PINK1 | c.1560G>A p.K520= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs764454206, COSV58632787, COSV58633025; called by muse, mutect2, varscan2
- POM121L12 | c.657C>A p.P219= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs766549462, COSV68692305; called by muse, mutect2, varscan2
- PRKG1 | c.168C>A p.A56= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100911327; called by muse, mutect2, varscan2
- PSMA8 | c.705A>G p.L235= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100378568; called by muse, mutect2, varscan2
- RAPH1 | c.1320G>A p.V440= (on ENST00000319170 / NM_213589.3; = p.V492= on NM_203365.4) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs759936432, COSV100050995; called by muse, mutect2, varscan2
- RASGRP3 | c.840C>T p.S280= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV101274652; called by muse, mutect2, varscan2
- RIMBP2 | c.3021C>A p.G1007= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99898053; called by muse, mutect2, varscan2
- RORB | c.657C>A p.T219= (on ENST00000396204 / NM_001365023.1; = p.T208= on NM_006914.4) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100974161, COSV65335187; called by muse, mutect2, varscan2
- RPRD2 | c.4077C>T p.G1359= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV100954830; called by muse, mutect2, varscan2
- SAMD7 | c.285T>C p.T95= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1018982231, COSV59420260; called by muse, mutect2
- SCAF8 | c.2862C>G p.P954= | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as COSV100913851; called by muse, mutect2, varscan2
- SDE2 | c.618T>C p.S206= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99682423; called by muse, mutect2, varscan2
- SERPINA7 | c.9A>T p.P3= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs751711434, COSV100568182; called by muse, varscan2
- SPPL2B | c.660C>T p.D220= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs764332708, COSV101194568; called by muse, varscan2
- STAG1 | c.2406C>T p.F802= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs936930327, COSV99364130; called by muse, mutect2, varscan2
- SYT12 | c.1038C>T p.P346= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1194304611, COSV101210795; called by muse, mutect2, varscan2
- TAOK3 | c.60T>A p.P20= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV101183376; called by muse, mutect2, varscan2
- TEX2 | c.3174G>C p.L1058= (on ENST00000583097 / NM_001288733.2; = p.L1065= on NM_018469.5) | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV99366675; called by muse, mutect2, varscan2
- TGIF2LX | c.405G>A p.L135= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs368668895, COSV99383144; called by muse, mutect2, varscan2
- THOC2 | c.3579G>A p.P1193= | Silent (SNP) | VAF 47/70 reads (67%) | catalogued as COSV99832592; called by muse, mutect2, varscan2
- TNXB | c.9660C>T p.T3220= (on ENST00000647633; = p.T2973= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100925681; called by muse, mutect2, varscan2
- TRPC7 | c.561C>T p.G187= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV61457172; called by muse, mutect2, varscan2
- VPS13B | c.10884G>A p.A3628= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs768029540, COSV62137624; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.9513T>G p.S3171= (on ENST00000628543; = p.S3346= on NM_152381.6) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99737351; called by muse, mutect2, varscan2
- ZEB2 | c.2869C>A p.R957= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV57955107, COSV57965320; called by muse, mutect2, varscan2
- ZNF460 | c.1233C>T p.F411= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV64415791; called by muse, mutect2, varscan2
- ZNF835 | c.1467C>G p.L489= | Silent (SNP) | VAF 121/334 reads (36%) | catalogued as COSV101606237, COSV73379805; called by muse, mutect2, varscan2
- ZSWIM1 | c.1392G>A p.R464= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99666010; called by muse, mutect2, varscan2
- ACSL6 | c.-21G>T | 5'UTR (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99732407; called by muse, mutect2, varscan2
- ADGRE4P | n.240T>G | RNA (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826222 G>A | 5'Flank (SNP) | VAF 57/232 reads (25%) | catalogued as rs1361335979; called by muse, mutect2, varscan2
- AGAP7P | n.374A>C | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845786 C>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1290A>T | RNA (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457491 C>G | 5'Flank (SNP) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- RAB28 | c.574-1284C>T | Intron (SNP) | VAF 18/70 reads (26%) | catalogued as rs372883609; called by muse, mutect2, varscan2
- SNORD116-4 | n.35T>C | RNA (SNP) | VAF 37/147 reads (25%) | catalogued as rs1338125507; called by muse, mutect2, varscan2
- WBP1LP2 | n.286T>G | RNA (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+8563G>T | Intron (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100371900; called by muse, mutect2, varscan2
